Somatic mutation profile of tumor specimen TCGA-HC-7213-01A (aliquot TCGA-HC-7213-01A-11D-2114-08) from TCGA case TCGA-HC-7213, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 53.9 years (19,699 days).
Specimen TCGA-HC-7213-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f86ea6c-b72b-48db-a3ca-29e107f3d8ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-7213-10A (Blood Derived Normal), aliquot TCGA-HC-7213-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5c9fbdc-8f0d-46d7-860b-cdb42df0fa41

The open-access MAF lists 34 somatic variants for this specimen: 27 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 23, Silent 7, Frame Shift Del 1, Frame Shift Ins 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.376-1G>A p.X126_splice | Splice Site (SNP) | VAF 13/19 reads (68%) | hotspot (GDC flag); catalogued as rs868137297, CS1313555, COSV52688618, COSV52749979, COSV52994579, COSV52996344; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- CARD18 | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73233234; called by muse, mutect2, varscan2
- CDH8 | c.641C>A p.P214H | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54895785; called by muse, mutect2, varscan2
- CDKL2 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV56735288; called by muse, mutect2, varscan2
- COL12A1 | c.8351C>T p.P2784L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.48); PolyPhen benign (0.046); catalogued as rs997353607, COSV59406250; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPNE9 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs775250719, COSV56069684; called by muse, mutect2, varscan2
- DIO3 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748146641, COSV100832156, COSV63774469; called by muse, mutect2
- DOK1 | c.971C>G p.A324G | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1201401858, COSV51212921; called by muse, mutect2, varscan2
- FASN | c.2299C>A p.L767M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV60760535; called by muse, mutect2, varscan2
- FBXO43 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1437390107, COSV71053270; called by muse, mutect2, varscan2
- FIBP | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.066); catalogued as rs1249662029, COSV57034246; called by muse, mutect2
- HFM1 | c.420G>C p.K140N | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.051); catalogued as COSV54036004; called by muse, mutect2, varscan2
- HTR3C | c.1313T>A p.I438N | Missense Mutation (SNP) | VAF 110/323 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV59177135; called by muse, mutect2, varscan2
- MAS1 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.042); catalogued as COSV53122118; called by muse, mutect2, varscan2
- NDST4 | c.1437C>A p.F479L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52116439, COSV52134750; called by muse, mutect2, varscan2
- NTM | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.202); catalogued as rs541916621, COSV66190571, COSV66191970; called by muse, mutect2, varscan2
- NTMT1 | c.529G>T p.D177Y | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52965833; called by muse, mutect2, varscan2
- OTX1 | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.317); catalogued as rs1210893213, COSV56996019; called by muse, mutect2
- PSG4 | c.211C>A p.Q71K | Missense Mutation (SNP) | VAF 80/253 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV54939964; called by muse, mutect2
- ROCK1 | c.515A>G p.E172G | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV67699020; called by muse, mutect2, varscan2
- SEMA6D | c.1459G>T p.V487F | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV60383057; called by muse, mutect2, varscan2
- TAOK2 | c.3293G>A p.R1098Q | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs970207198, COSV54229577; called by muse, mutect2
- UBR3 | c.4547T>A p.M1516K | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV55858884; called by muse, mutect2, varscan2
- ZNF585B | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.439); catalogued as rs147861258; called by muse, mutect2
- ABCC4 | c.1199_1204del p.R400_Q401del | In Frame Del (DEL) | VAF 7/58 reads (12%) | called by mutect2, pindel
- HSPA9 | c.1894_1895del p.N632Yfs*2 | Frame Shift Del (DEL) | VAF 70/182 reads (38%) | called by mutect2, pindel, varscan2
- SRSF3 | c.256dup p.R86Kfs*3 | Frame Shift Ins (INS) | VAF 27/130 reads (21%) | called by mutect2, pindel, varscan2
- ADAMTS10 | c.456C>T p.D152= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as rs371629978; called by muse, mutect2, varscan2
- ASB17 | c.261C>T p.L87= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs11811988, COSV52409902; called by muse, mutect2, varscan2
- DLG4 | c.1752G>A p.S584= (on ENST00000399506 / NM_001321075.3; = p.S627= on NM_001365.4) | Silent (SNP) | VAF 63/110 reads (57%) | catalogued as rs376280525; called by muse, mutect2, varscan2
- EI24 | c.588C>A p.I196= | Silent (SNP) | VAF 130/349 reads (37%) | catalogued as COSV54020897; called by muse, mutect2, varscan2
- MKI67 | c.9276C>T p.R3092= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV64074215; called by muse, mutect2
- PLSCR1 | c.279A>G p.L93= | Silent (SNP) | VAF 74/193 reads (38%) | catalogued as COSV61013765; called by muse, mutect2, varscan2
- SORCS3 | c.2631C>T p.D877= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as rs143982937; called by muse, mutect2, varscan2
